Surgical pathology report (de-identified scan), TCGA case TCGA-06-5408, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-5408-01A (Primary Tumor).

[page 1 of 4]
TCGA-06-5408

Surgical Pathology Report

=====

CLINICAL HISTORY

Left frontal mass

OPERATIVE DIAGNOSES

Operation/Specimen: A: Brain, left frontal mass, biopsy
B: Brain, left frontal mass, biopsy

PATHOLOGICAL DIAGNOSIS:

A. and B. Brain, left frontal tumor, excision: Glioblastoma (WHO Grade IV)
(see comment).

COMMENT

Sections show a densely cellular tumor demonstrating vascular proliferation and necrosis. The tumor cells are diffusely positive for GFAP and p53. The Ki-67 labeling index is variable, but is focally up to 60% in several areas. Results of MGMT promoter methylation and EGFRvIII mutation assays will be reported below in procedure addenda.

=====

PROCEDURES/ADDENDA

PCR for EGFR variant III mutation

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

POSITIVE - EGFRvIII mutation is detected

Results-Comments

[page 2 of 4]
TEST DESCRIPTION: Testing performed on RNA extracted from tumor paraffin block

The epidermal growth factor receptor (EGFR) is an attractive molecular target

in glioblastoma because it is amplified, overexpressed, and/or mutated in up to 40% to 50% of patients. Epidermal growth factor receptor variant III (EGFRvIII) is an oncogenic, constitutively active mutant form of EGFR that is

commonly expressed in glioblastoma. Cell culture and in vivo models of glioblastoma have demonstrated EGFRvIII as defining prognostically distinct subgroups of glioblastomas. Additionally, the presence of EGFRvIII has been shown to sensitize tumors to EGFR tyrosine kinase inhibitors when the tumor suppressor protein PTEN is intact. RNA is extracted from formalin fixed, paraffin embedded tissue samples and reverse transcribed to cDNA. The cDNA is

then amplified using standard PCR technique for DNA templates. PCR products are detected by gel electrophoresis. The limit of detection of this assay has

been determined to be approximately 5 mutant cells in 100 normal cells.

FDA Comment: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

[REDACTED]

Interpretation

NEGATIVE: No evidence of methylated MGMT promoter is detected.

Results-Comments

Testing performed on DNA extracted from tumor paraffin block.

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit from therapy with alkylating agents. Assessment of

MGMT promoter methylation status involves bisulfite treatment of DNA followed

by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA sequences.

[page 3 of 4]
The analytic sensitivity of this assay was determined by serial dilution of methylated positive control DNA into unmethylated DNA, and was assessed to be

1% of methylated DNA in the background of unmethylated DNA. Factors such as the presence of >50% non-neoplastic cells in the sample, or extensive tissue necrosis, may preclude the detection of methylated MGMT promoter sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

=====

INTRA-OPERATIVE CONSULTATION

A. Brain, left frontal mass, biopsy: High-grade glioma. Frozen section and smears performed at [REDACTED] and results reported to the Physician of Record. [REDACTED]

[REDACTED]

GROSS DESCRIPTION

A. Received fresh are fragments of tan tissue, approximately 0.5 x 0.5 x 0.3 cm in aggregate. Small samples are used for intraoperative frozen sections and smears. The frozen residual is submitted in A1 and the unfrozen issue is submitted in A2.

B. Received fresh is a single portion of tan tissue, approximately 1.0 x 0.9 x 0.4 cm. Approximately 1/3 of the tissue is submitted in B1. The remainder of the tissue is submitted for snap freezing and storage in the [REDACTED] per the surgeon's request.

[REDACTED]

ICD-9(s):

225.0 225.0

[REDACTED]

[page 4 of 4]
Histo Data

Part A: Brain, left frontal mass, biopsy

Taken: [REDACTED]	Received: [REDACTED]		
Stain/cnt	Block	Ordered	Comment
FS H/E x 1	1	[REDACTED]	
H/E x 1	1	[REDACTED]	
TPS H/E x 1	1	[REDACTED]	
H/E x 1	2	[REDACTED]	

Part B: Brain, left frontal mass, biopsy

Taken: [REDACTED]	Received: [REDACTED]		
Stain/cnt	Block	Ordered	Comment
EGFR vIII-curls x 1	1	[REDACTED]	
H/E x 1	1	[REDACTED]	
MGMT-curls x 1	1	[REDACTED]	
MIB1-DA x 1	1	[REDACTED]	
P53D07 x 1	1	[REDACTED]	

*** End of Report ***

Source: NCI Genomic Data Commons file 1b66ef06-2ff1-47f3-904e-ffac6a98aa3c (TCGA-06-5408.DAFE8753-D5CC-415B-A1DF-8317A027C088.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).